Gene-level copy-number profile of tumor specimen TCGA-78-7220-01A from TCGA case TCGA-78-7220, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.3 years (19,480 days).
Specimen TCGA-78-7220-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d4b9bf79-62a5-41d5-aaec-60f616705dfa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7220-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24d2657d-0f37-4a7c-a079-fd566ca3beab

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 2,948; copy number 2: 31,415; copy number 3: 12,771; copy number 4: 11,230; copy number 5: 464; copy number 6: 182; copy number 7: 6; copy number 8: 538; copy number 9: 187; copy number 10: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7220-01A-11D-2035-01): tumor purity 0.61, ploidy 2.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:61,870,097–61,893,882, 1 gene: AL355347.1.
- chr9:19,789,179–23,438,700, 75 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,379 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:166,160,021–169,966,734, 62 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr4:499,210–1,395,989, 39 genes, copy number 6 (within-gene range 4–6): PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1, CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA, UVSSA, AC078852.2, AC078852.1.
- chr4:39,399,149–39,638,902, 12 genes, copy number 6 (within-gene range 4–6): RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1, UGDH, UGDH-AS1, AC021148.2, SMIM14, AC108471.3.
- chr5:58,198–45,895,970, 710 genes, copy number 8–10 (broad region; genes not listed).
- chr6:40,271,566–42,979,181, 82 genes, copy number 5–6 (broad region; genes not listed).
- chr6:45,328,157–46,491,972, 10 genes, copy number 5 (within-gene range 4–5): RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2.
- chr6:49,565,924–49,820,503, 6 genes, copy number 7 (within-gene range 4–7): CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3.
- chr6:145,382,535–148,648,597, 41 genes, copy number 5–8: EPM2A, RNU1-33P, AL031119.1, AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT, SHPRH, GRM1, FUNDC2P3, RNA5SP222, AL035698.1, RAB32, AL359547.1, ADGB, AL359547.2, RNU6-906P, KATNBL1P6, STXBP5-AS1, AL138916.1, AL138916.2, LUADT1, STXBP5, AL355365.1, YAP1P1, SAMD5, AL033504.1, AL365271.1, AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40.
- chr7:124,032,126–125,933,832, 19 genes, copy number 5 (within-gene range 3–5): AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1, AC010099.2, PPIAP93, AC003975.1.
- chr8:141,786,242–142,403,182, 8 genes, copy number 5 (within-gene range 3–5): MIR1302-7, AC104417.1, AC104417.2, AC103758.1, MIR4472-1, LINC00051, TSNARE1, RN7SL260P.
- chr11:87,258,851–87,606,885, 7 genes, copy number 5: AP001102.1, AP000811.1, PSMA2P1, AP003497.1, AP003497.2, AP001784.1, RNU6-1135P.
- chr12:459,939–911,452, 10 genes, copy number 6 (within-gene range 4–6): B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1.
- chr12:115,755,262–118,372,907, 48 genes, copy number 6–9 (within-gene range 4–9): AC009387.1, LINC02463, AC012157.1, AC012157.3, MED13L, AC012157.2, RNU6-1188P, MIR620, SNRPGP18, AC130895.1, AC079384.2, AC079384.1, MIR4472-2, LINC02457, LINC00173, MAP1LC3B2, AC125603.4, AC125603.3, AC125603.2, AC125603.1, SPRING1, RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5.
- chr14:89,794,669–92,935,285, 61 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:17,674,026–22,706,703, 264 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,802. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
